Somatic mutation profile of tumor specimen MP2PRT-PAPCVR-TMP1-A (aliquot MP2PRT-PAPCVR-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPCVR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Precursor cell lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,029 days).
Specimen MP2PRT-PAPCVR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12b610bd-2c28-4a2e-8e7c-ff762d5b818e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPCVR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPCVR-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a73c9a78-ebaa-423e-a4a1-fe73593855a1

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HMGCS1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 93/349 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57289812; called by muse, mutect2, varscan2
- MTA2 | c.317G>A p.C106Y | Missense Mutation (SNP) | VAF 89/301 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53873436; called by muse, mutect2, varscan2
- NLRP12 | c.1453G>A p.G485S | Missense Mutation (SNP) | VAF 131/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1268047610, COSV60745387, COSV60756025; called by muse, mutect2, varscan2
- RASA3 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 70/257 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373938545, COSV61866679; called by muse, mutect2, varscan2
- AMPH | c.1513del p.V505* | Frame Shift Del (DEL) | VAF 98/354 reads (28%) | called by mutect2, pindel, varscan2
- CCAR2 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DZANK1 | c.1430G>C p.R477T (on ENST00000262547 / NM_001099407.1; = p.R284T on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- IGHV3-48 | c.352_353delinsAAAAAGACCC | In Frame Ins (INS) | VAF 60/213 reads (28%) | called by pindel, varscan2*
- SPATA31A1 | c.3762C>G p.F1254L | Missense Mutation (SNP) | VAF 164/625 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CLCN6 | c.2586G>A p.L862= | Silent (SNP) | VAF 77/315 reads (24%) | catalogued as COSV56743673; called by muse, mutect2, varscan2
